Surgical pathology report (de-identified scan), TCGA case TCGA-XM-AAZ1, project TCGA-THYM (Thymoma), tissue source site MSKCC, specimen TCGA-XM-AAZ1-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY REPORT

Patient: [REDACTED] Accession #: [REDACTED]
MRN: [REDACTED] Service: Thoracic
Account #: [REDACTED] Date of Procedure:
[REDACTED] (Age: M Date of Receipt:
Physician: [REDACTED] Date of Report:
CC: [REDACTED]
Patient Address: [REDACTED]

....

Clinical Diagnosis & History:

Anterior mediastinal mass.

Specimens Submitted:

1: Anterior mediastinal mass (fs)

DIAGNOSIS:

1. Mediastinal mass; resection: *Per TSS, TCGA tumor = 02.*
- Thymoma, WHO type B2/B3.
- Tumor size: 6.6 cm.
- The tumor extends through the capsule into fibroadipose tissue.
- No lymphovascular invasion identified.
- The tumor focally extends to the cauterized resection margin.

See note:

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

1) The specimen is received fresh for frozen section, labeled "Anterior mediastinal mass", and consists of a tan-gray, smooth, rubbery mass measuring 6.6 x 5.0 x 3.1 cm with an attached portion of tan-brown, lobulated soft tissue measuring 4.5 x 3.0 x 1.4 cm. The specimen is inked black and serially sectioned to reveal the mass is circumscribed, with tan-gray, soft, focally hemorrhagic cut surfaces with a focal bright yellow

** Continued on next page **

054 ICD-O 3
Thymoma, type B2, malignant
path 8584/3
Thymoma, type B2/B3,
malignant 8585/3
Site: Anterior mediastinum
C38.1
JW 3/12/14

[page 2 of 3]
SURGICAL PATHOLOGY REPORT

Patient:

MRN:

Account #:

Accession #: [REDACTED]

Physician:

Service: Thoracic

Date of Report:

----- Page 2 of 2
area measuring 1.8 x 0.5 x 0.3 cm located on the periphery. The remaining uninvolved soft tissue is brown and tan and grossly unremarkable. The mass is grossly 90% viable. Pictures are taken. The specimen is mapped. Representative sections are submitted.

Summary of sections:

A-H Full cross section of specimen (submitted left to right and top to bottom)

Summary of Sections:

Part 1: Anterior mediastinal mass (fs)

Blocks	Block Designation	PCs
1	{not entered}	
1	A 1	
1	B 1	
1	C 1	
1	D 1	
1	E 1	
1	F 1	
1	G 1	
1	H 1	

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

1) FROZEN SECTION DIAGNOSIS: Thymic epithelial tumor, favor thymoma.

PERMANENT DIAGNOSIS: Same

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

1) FROZEN SECTION DIAGNOSIS: Thymic epithelial tumor, favor thymoma.

PERMANENT DIAGNOSIS: Same

**** End of Report ****

Pw TSS dx discrepancy form, TC6A
tumor is categorized as B2.

[page 3 of 3]
TCGA Pathologic Diagnosis Discrepancy Form

V4.00

Instructions: The TCGA Pathologic Diagnosis Discrepancy Form should be completed when the pathologic diagnosis documented on the initial pathology report for a case submitted for TCGA is inconsistent with the diagnosis provided on the Case Quality Control Form completed for the submitted case.

Tissue Source Site (TSS): _____ TSS Identifier: _____ TSS Unique Patient Identifier: _____

Completed By (Interviewer Name on _____) Completed Date: _____

Diagnosis Information

#	Data Element	Entry Alternatives	Working Instructions
1	Pathologic Diagnosis Provided on Initial Pathology Report	B2/B3	Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.
2	Histologic features of the sample provided for TCGA, as reflected on the CQCF.	B2	Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.

Discrepancy between Pathology Report and Case Quality Control Form

3	Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form.	does not allow for a value of B2/B3, therefore, B2 was selected.	Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.
4	Name of TSS Reviewing Pathologist or Biorepository Director	_____	Provide the name of the pathologist who reviewed this case for TCGA.

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled.

TSS Reviewing Pathologist or Biorepository Director

Date

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled. The Attending Pathologist or the Department Chairman has been informed or is aware of the above discrepancy in diagnoses.

Principal Investigator Signature

Date

Source: NCI Genomic Data Commons file 009f045a-2822-452a-aaf9-85dc094456f6 (TCGA-XM-AAZ1.5E99CD84-AA23-4532-B361-34899DD5BA64.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).